Somatic mutation profile of tumor specimen TCGA-17-Z025-01A (aliquot TCGA-17-Z025-01A-01W-0746-08) from TCGA case TCGA-17-Z025, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77c1ae1d-5940-46c6-b186-9b09b5a30058.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z025-11A (Solid Tissue Normal), aliquot TCGA-17-Z025-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a20cd8d-24b7-43cc-930e-06c6c7c7fb59

The open-access MAF lists 260 somatic variants for this specimen: 200 protein-altering or splice-affecting, 53 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 53, Nonsense Mutation 16, Frame Shift Del 6, Intron 4, Splice Region 3, Frame Shift Ins 1, Splice Site 1, 5'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SNRPD3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 39/94 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV53183301, COSV53184122; called by muse, mutect2, varscan2
- ADCY3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.114); catalogued as COSV53169818; called by muse, mutect2, varscan2
- ADGRG4 | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54959712; called by muse, mutect2, varscan2
- ADGRL3 | c.1357G>T p.V453L (on ENST00000506720 / NM_001322402.2; = p.V385L on NM_015236.6) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.085); catalogued as COSV72265533; called by muse, mutect2, varscan2
- ARHGAP17 | c.1434G>T p.E478D | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as rs1206858351; called by muse, mutect2, varscan2
- ASTN2 | c.1820A>G p.E607G (on ENST00000313400 / NM_001365069.1; = p.E556G on NM_014010.5) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV57813521; called by muse, mutect2, varscan2
- ATRNL1 | c.1552G>T p.G518W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61803056; called by muse, mutect2, varscan2
- ATRX | c.5879C>G p.S1960* | Nonsense Mutation (SNP) | VAF 16/394 reads (4%) | catalogued as COSV64872073; called by muse, mutect2
- BMS1 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65733166; called by muse, mutect2, varscan2
- BOD1L1 | c.8249G>T p.S2750I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1372565936; called by muse, mutect2
- BRCA2 | c.4195T>C p.C1399R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.73); catalogued as rs730881530; ClinVar: uncertain significance; called by mutect2, varscan2
- BSND | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs199832638; called by muse, mutect2, varscan2
- CAMKV | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs762722820; called by muse, mutect2, varscan2
- CASQ2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1201611564; called by muse, mutect2, varscan2
- CASQ2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1230737146; called by muse, mutect2, varscan2
- CCN4 | c.667T>A p.W223R | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51530242; called by muse, mutect2, varscan2
- CDH5 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs1415492509, COSV104419685; called by muse, mutect2
- CDH6 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV54065109; called by muse, mutect2, varscan2
- COL5A3 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1270569142; called by muse, mutect2, varscan2
- CRB1 | c.4000G>C p.V1334L | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs754862028, CD130813; called by muse, mutect2, varscan2
- DHX40 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs754573837; called by muse, mutect2, varscan2
- DLC1 | c.4492A>T p.K1498* (on ENST00000276297 / NM_001348081.2; = p.K1061* on NM_006094.5) | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99365232; called by muse, mutect2, varscan2
- EPHA3 | c.2686G>T p.A896S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60719749; called by muse, mutect2, varscan2
- EPHA6 | c.486del p.R162Sfs*11 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as COSV67594437; called by mutect2, pindel, varscan2
- FBN1 | c.6517G>T p.G2173C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM161873, BM1157862; called by muse, mutect2, varscan2
- FLG | c.4480G>A p.G1494R | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV64236137; called by muse, mutect2, varscan2
- FLT1 | c.3074C>G p.A1025G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56738663, COSV99149343; called by muse, mutect2, varscan2
- GABRA2 | c.638C>A p.S213Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV62915682, COSV62916534, COSV62918977; called by muse, mutect2, varscan2
- HCN1 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57521231, COSV57539402; called by muse, mutect2, varscan2
- HMGCLL1 | c.789G>T p.L263F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs745968835; called by muse, mutect2, varscan2
- INTU | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99611500; called by muse, mutect2, varscan2
- IRGQ | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.996); catalogued as rs1469227166; called by muse, mutect2, varscan2
- ITGAE | c.2158C>A p.L720I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as COSV53993464; called by muse, mutect2
- KMT2C | c.11570C>T p.T3857M | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs577099359, COSV51282297, COSV51441373; ClinVar: not provided; called by muse, mutect2, varscan2
- LAMC1 | c.4360G>T p.V1454F | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99279227; called by muse, mutect2, varscan2
- MYOF | c.1444G>C p.A482P | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100825661; called by muse, mutect2, varscan2
- NAA80 | c.260G>A p.R87H (on ENST00000417393 / NM_001200018.2; = p.R109H on NM_012191.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs782215726, COSV56499668; called by muse, mutect2, varscan2
- NEK3 | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1462686773; called by muse, mutect2
- NGEF | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as rs1358015158; called by muse, mutect2, varscan2
- NIN | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1205506022; called by muse, mutect2, varscan2
- OR14K1 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs968561778; called by muse, mutect2, varscan2
- OR1J2 | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs1171969583; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.146G>A p.R49Q (on ENST00000374531 / NM_001037293.2; = p.R47Q on NM_007203.5) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1169178652; called by muse, mutect2
- PARD3B | c.1271A>G p.D424G | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293178555; called by muse, mutect2, varscan2
- PCDH17 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); catalogued as rs769022430; called by muse, mutect2, varscan2
- PCDHB8 | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as COSV99177025; called by muse, mutect2, varscan2
- PCLO | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1387269483; called by muse, mutect2, varscan2
- PDE11A | c.2165C>A p.A722D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV53711062; called by muse, mutect2, varscan2
- PITPNM3 | c.2296G>T p.D766Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262820076; called by muse, mutect2, varscan2
- PMEPA1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs904658844; called by muse, mutect2, varscan2
- RANBP3 | c.775G>T p.A259S (on ENST00000340578 / NM_007322.3; = p.A254S on NM_003624.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as rs528212129; called by muse, varscan2
- ROBO4 | c.2713C>A p.H905N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1201427249, COSV100127615; called by muse, mutect2, varscan2
- RTL1 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1424273138; called by muse, mutect2, varscan2
- SAAL1 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55517696; called by muse, varscan2
- SIGLEC5 | c.1079C>A p.A360D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418073641; called by muse, mutect2, varscan2
- SIGLEC6 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.933); catalogued as COSV100585617; called by muse, mutect2, varscan2
- SIK3 | c.896G>T p.R299L (on ENST00000445177 / NM_001366686.2; = p.R305L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99408733; called by muse, mutect2, varscan2
- SLC14A2 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1250203879; called by muse, mutect2, varscan2
- SPATA18 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV54641676; called by muse, mutect2
- SPTA1 | c.1490C>A p.A497D | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199604294, COSV63755058; called by muse, mutect2, varscan2
- STX1B | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1471564338; called by muse, mutect2, varscan2
- SVOPL | c.550G>T p.G184C (on ENST00000419765; = p.G32C on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55989172; called by muse, mutect2, varscan2
- TCHH | c.1831G>T p.E611* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | catalogued as COSV64272571; called by muse, varscan2
- TENM3 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 41/85 reads (48%) | catalogued as COSV101305168; called by muse, mutect2, varscan2
- TMEM145 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as COSV99236175; called by muse, mutect2, varscan2
- TNNI3 | c.504C>A p.D168E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1344349140; called by muse, mutect2, varscan2
- TNS3 | c.2475G>C p.Q825H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV60793095; called by muse, mutect2, varscan2
- TRHDE | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.629); catalogued as COSV99670855; called by muse, mutect2
- TRHDE | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1446950309; called by muse, mutect2, varscan2
- TRPS1 | c.2945G>T p.R982M (on ENST00000220888 / NM_001330599.2; = p.R995M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as CD155659; called by muse, mutect2, varscan2
- UBE2E2 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV100232616; called by muse, varscan2
- UNC93A | c.501G>A p.E167= | Splice Region (SNP) | VAF 6/14 reads (43%) | catalogued as rs1463489085; called by muse, mutect2
- VWA3B | c.992C>A p.A331D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1218918617; called by muse, mutect2, varscan2
- WAS | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV61920215; called by muse, mutect2
- WDTC1 | c.1186G>C p.A396P (on ENST00000319394 / NM_001276252.2; = p.A395P on NM_015023.5) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as rs1295383162; called by muse, mutect2, varscan2
- WEE2 | c.1149C>A p.H383Q | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV66879933; called by muse, mutect2, varscan2
- ZNF536 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100834760, COSV62822939; called by muse, mutect2, varscan2
- ZNF568 | c.979A>T p.I327F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100451519; called by muse, mutect2, varscan2
- ZNF91 | c.3160G>T p.E1054* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as rs1382348870; called by muse, mutect2, varscan2
- ZNF98 | c.1097C>A p.T366N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs758012425; called by mutect2, varscan2
- AADAT | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG7 | c.1136A>C p.Y379S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2
- AIM2 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- AKAP13 | c.4161+1G>C p.X1387_splice | Splice Site (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- ALK | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- ALLC | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANGPT1 | c.901A>T p.T301S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANXA5 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.143); called by muse, mutect2
- ARHGAP30 | c.2726G>T p.C909F (on ENST00000368013 / NM_001025598.2; = p.C698F on NM_181720.3) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ARMCX3 | c.179G>A p.W60* | Nonsense Mutation (SNP) | VAF 14/421 reads (3%) | called by muse, mutect2
- ARRDC4 | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ATRX | c.3942G>T p.E1314D | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1orf162 | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- C1orf87 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, varscan2
- CACNA1A | c.3622G>T p.E1208* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- CACNA1E | c.2972G>T p.R991I | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- CAMKV | c.910A>T p.I304F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CCNYL1 | c.761A>T p.N254I (on ENST00000295414 / NM_001330218.2; = p.N184I on NM_152523.2) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CENPJ | c.3381G>T p.R1127S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPJ | c.3380G>T p.R1127M | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CEP112 | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP128 | c.1242A>T p.K414N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); called by mutect2, varscan2
- CRACD | c.3521C>T p.T1174I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRTAM | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- DENND5B | c.880A>G p.M294V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DMXL1 | c.5985A>T p.K1995N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSP | c.3005G>T p.R1002L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DTNA | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ERCC6 | c.4046C>A p.P1349Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ERCC6L2 | c.4085G>T p.S1362I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ERICH3 | c.2896A>T p.R966* | Nonsense Mutation (SNP) | VAF 41/149 reads (28%) | called by muse, mutect2, varscan2
- FAM83D | c.1358C>A p.P453H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FLI1 | c.1063A>T p.R355* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- GCC1 | c.2041G>T p.V681L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGCX | c.561T>G p.N187K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GJB6 | c.371del p.Q124Rfs*5 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- GPR65 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GYS2 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- HSPG2 | c.11521G>T p.G3841C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTR1F | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- IBTK | c.2739T>A p.D913E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- IGHV3-16 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 99/474 reads (21%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL12RB1 | c.1200C>A p.S400R | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ITPR2 | c.7030A>G p.M2344V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KIAA1549 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KIFAP3 | c.686A>G p.H229R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LARS1 | c.332A>G p.Y111C (on ENST00000394434 / NM_020117.11; = p.Y84C on NM_016460.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LAX1 | c.272A>T p.N91I | Missense Mutation (SNP) | VAF 65/408 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRB2 | c.1691A>T p.Q564L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LMTK2 | c.2675A>G p.E892G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRPPRC | c.1394dup p.M465Ifs*9 | Frame Shift Ins (INS) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- LRRC6 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LTBP1 | c.4914G>T p.R1638S (on ENST00000404816 / NM_206943.4; = p.R1312S on NM_000627.4) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEB6B | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MAGEL2 | c.2722T>A p.W908R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- MINDY1 | c.1087_1090del p.D363Ffs*3 | Frame Shift Del (DEL) | VAF 75/263 reads (29%) | called by mutect2, pindel, varscan2
- MOV10L1 | c.1687G>C p.G563R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC16 | c.28984A>T p.I9662F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- MYH3 | c.4280A>G p.E1427G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MYH4 | c.4997G>T p.R1666I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MYH6 | c.5292C>A p.A1764= | Splice Region (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- NDUFB5 | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.081); called by muse, mutect2
- NEK10 | c.3336C>A p.N1112K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEK5 | c.1193C>A p.P398Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NEUROD2 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.108); called by muse, mutect2
- NSUN2 | c.1322A>T p.K441M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NXPE1 | c.1591C>A p.P531T (on ENST00000424269; = p.P389T on NM_152315.5) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- OR10K2 | c.221C>G p.T74S | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OR13G1 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2G6 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- OR4K13 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR4S2 | c.877A>G p.K293E | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR52J3 | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- OR52N1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAMR1 | c.556del p.D186Mfs*25 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- PCDH1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 52/192 reads (27%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA8 | c.990G>T p.R330S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PGK2 | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3C3 | c.2137G>T p.G713W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEC | c.10466A>C p.Q3489P (on ENST00000322810 / NM_201380.4; = p.Q3379P on NM_000445.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- PLEKHA7 | c.451_452delinsT p.G151* | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | called by pindel, varscan2*
- PLK1 | c.1252T>G p.S418A | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- RALGAPA1 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- RCN1 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RELN | c.133del p.E45Sfs*32 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- RP1L1 | c.1678A>T p.R560W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPL7L1 | c.39A>T p.Q13H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RUBCNL | c.1777G>T p.G593C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SEMA3E | c.2156A>G p.Y719C | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SI | c.3430C>A p.L1144I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2
- SIRPB2 | c.82T>A p.S28T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.188); called by muse, mutect2
- SLC15A1 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SLC45A2 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- SORCS1 | c.2381G>T p.G794V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SPEG | c.3521C>A p.P1174H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SV2C | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- SYNE1 | c.7969A>C p.K2657Q (on ENST00000367255 / NM_182961.4; = p.K2664Q on NM_033071.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX45 | c.998A>G p.Y333C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TFCP2 | c.859A>G p.N287D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by mutect2, varscan2
- TMEM121B | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.170T>A p.L57H | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.2); called by muse, mutect2
- TPR | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- TPTE | c.77G>T p.S26I | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); called by muse, mutect2
- TRBV6-1 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TTLL7 | c.1992G>T p.V664= | Splice Region (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- TYR | c.266G>T p.C89F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UBR5 | c.1482G>T p.W494C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- UHRF1BP1L | c.3262G>T p.E1088* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- ULK2 | c.1333G>T p.G445C | Missense Mutation (SNP) | VAF 101/211 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VGLL3 | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- VIT | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- VIT | c.390A>T p.R130S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZFR | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- ZNF215 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF260 | c.147T>A p.H49Q | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZNF676 | c.1579C>A p.H527N (on ENST00000650058; = p.H495N on NM_001001411.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF695 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ZNF713 | c.443A>G p.K148R (on ENST00000633730 / NM_001366796.2; = p.K161R on NM_182633.3) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNRF4 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK1 | c.4095C>A p.P1365= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- ANK3 | c.4551C>T p.A1517= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- ANKRD1 | c.507G>T p.V169= | Silent (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- APOB | c.3960C>A p.A1320= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV51943863; called by muse, mutect2, varscan2
- ARHGAP30 | c.2727T>C p.C909= (on ENST00000368013 / NM_001025598.2; = p.C698= on NM_181720.3) | Silent (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- ARSF | c.1269C>A p.V423= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1412634602, COSV63841194; called by muse, mutect2, varscan2
- C9orf50 | c.912C>A p.A304= | Silent (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- CAND1 | c.1896G>A p.L632= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV73389615; called by muse, mutect2
- CD200R1 | c.771C>A p.I257= (on ENST00000471858 / NM_170780.3; = p.I280= on NM_138806.4) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV55600674; called by muse, mutect2, varscan2
- CEP350 | c.4524T>G p.S1508= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1309605916; called by muse, mutect2, varscan2
- CFAP20DC | c.2019G>A p.E673= (on ENST00000482387 / NM_001351530.2; = p.E422= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- CRYBG1 | c.2226G>C p.V742= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- CSMD2 | c.5589G>A p.L1863= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV53965103; called by muse, mutect2, varscan2
- CYP2C8 | c.1080C>T p.D360= | Silent (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- DNAH2 | c.3270T>C p.T1090= | Silent (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- DNASE2B | c.75G>T p.L25= | Silent (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- EMP3 | c.132G>T p.T44= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs139549534; called by muse, mutect2, varscan2
- FOXP4 | c.1281G>T p.L427= (on ENST00000307972 / NM_001012426.1; = p.L414= on NM_138457.3) | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1380377338; called by muse, mutect2, varscan2
- GLYATL1 | c.405G>A p.T135= (on ENST00000317391 / NM_001354699.1; = p.T166= on NM_080661.4) | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs370872373; called by muse, mutect2, varscan2
- HTR3A | c.912C>A p.L304= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- ITPR2 | c.5952G>C p.L1984= | Silent (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- KCNH4 | c.1581C>T p.D527= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1382569454, COSV52916145; called by muse, mutect2, varscan2
- KIAA1755 | c.270C>A p.V90= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as COSV54075808; called by muse, mutect2, varscan2
- KIAA1958 | c.846G>A p.Q282= | Silent (SNP) | VAF 41/376 reads (11%) | called by muse, mutect2, varscan2
- KIAA2026 | c.4785A>G p.S1595= | Silent (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- MED24 | c.876G>T p.G292= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs1234662037; called by muse, mutect2, varscan2
- NDUFS2 | c.57G>T p.R19= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs779864852; called by muse, mutect2
- NOD2 | c.777C>A p.V259= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- NRSN1 | c.270C>T p.I90= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as rs770598939, COSV65893738; called by muse, mutect2, varscan2
- OR1A2 | c.609C>T p.V203= | Silent (SNP) | VAF 38/188 reads (20%) | catalogued as rs150553361; called by muse, mutect2, varscan2
- OR5M1 | c.225C>T p.S75= | Silent (SNP) | VAF 38/164 reads (23%) | called by muse, mutect2, varscan2
- PDCD11 | c.1248T>C p.T416= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- PHLDB1 | c.699G>T p.L233= | Silent (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- PITPNM3 | c.2295G>T p.V765= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- PRDM9 | c.1110C>A p.G370= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs1490555656, COSV57011700; called by muse, mutect2, varscan2
- RCN1 | c.669G>T p.V223= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- RHAG | c.972C>A p.I324= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs1265797315, COSV100006349; called by muse, mutect2, varscan2
- RYR2 | c.4608T>C p.S1536= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- RYR2 | c.10038G>T p.G3346= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- SEMA3D | c.135C>A p.L45= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1167245175; called by muse, varscan2
- SEMA4A | c.1476G>T p.V492= | Silent (SNP) | VAF 114/690 reads (17%) | called by muse, mutect2, varscan2
- SI | c.3657A>C p.P1219= | Silent (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- SMG1 | c.1852C>T p.L618= | Silent (SNP) | VAF 26/106 reads (25%) | called by muse, varscan2
- STAB2 | c.6757C>A p.R2253= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs374688619; called by muse, mutect2, varscan2
- STYXL2 | c.3252C>T p.A1084= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV54810332; called by muse, mutect2
- TENM4 | c.6237C>T p.A2079= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- TEX14 | c.4263G>T p.V1421= (on ENST00000240361 / NM_001201457.2; = p.V1375= on NM_031272.5) | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- THSD1 | c.669G>T p.G223= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV51627976; called by muse, mutect2, varscan2
- TMEM145 | c.1287G>T p.G429= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.19356A>T p.I6452= (on ENST00000591111; = p.I5525= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- ULK4 | c.3348C>T p.H1116= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as rs1211739465; called by muse, mutect2
- ZNF165 | c.744G>C p.S248= | Silent (SNP) | VAF 40/144 reads (28%) | called by muse, mutect2, varscan2
- ZNF98 | c.1098T>A p.T366= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs752357185; called by mutect2, varscan2
- AMELX | c.103-131C>G | Intron (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- ANK2 | c.2900+5162G>T | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- MIR519A2 | n.72G>T | RNA (SNP) | VAF 13/106 reads (12%) | called by muse, mutect2, varscan2
- OFCC1 | n.556+3421C>A | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, varscan2
- RN7SL484P | chr15:99790908 G>T | 5'Flank (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12709T>G | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- ZNF99 | c.*314A>T | 3'UTR (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
